Somatic mutation profile of tumor specimen ALCH-B3G7-TTP1-A (aliquot ALCH-B3G7-TTP1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-B3G7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.4 years (25,718 days).
Specimen ALCH-B3G7-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2b0067a-ed2c-4fd0-84b7-1be46efe5167.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3G7-NB1-A (Blood Derived Normal), aliquot ALCH-B3G7-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d4e270a-961f-4217-b796-bcb2090d7d4f

The open-access MAF lists 146 somatic variants for this specimen: 107 protein-altering or splice-affecting, 26 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 95, Silent 26, Intron 6, Nonsense Mutation 5, Splice Site 4, 3'UTR 2, Splice Region 2, 5'UTR 2, RNA 1, Frame Shift Del 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARMH4 | c.1502C>T p.P501L | Missense Mutation (SNP) | VAF 31/386 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs777748590; called by muse, mutect2
- ATAD3B | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.981); catalogued as rs1352789193; called by muse, mutect2
- ATP6V1B1 | c.686G>A p.G229E | Missense Mutation (SNP) | VAF 21/296 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1553419986; called by muse, mutect2
- B4GALT4 | c.713T>C p.L238P | Missense Mutation (SNP) | VAF 14/368 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1487103752; called by muse, mutect2
- C9 | c.618C>T p.T206= | Splice Region (SNP) | VAF 11/158 reads (7%) | catalogued as COSV54679001; called by muse, mutect2
- CCDC175 | c.1471C>T p.R491* | Nonsense Mutation (SNP) | VAF 8/112 reads (7%) | catalogued as rs1372982767; called by muse, mutect2
- CLNK | c.424G>T p.V142F | Missense Mutation (SNP) | VAF 30/290 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as rs376833668; called by muse, mutect2, varscan2
- CNFN | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV99706216; called by muse, mutect2, varscan2
- DMD | c.4394C>A p.A1465D | Missense Mutation (SNP) | VAF 62/537 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs755496708; called by muse, mutect2, varscan2
- ELL2 | c.656A>G p.Y219C | Missense Mutation (SNP) | VAF 19/430 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52984497; called by muse, mutect2
- F13A1 | c.2115G>T p.K705N | Missense Mutation (SNP) | VAF 24/318 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746057077; called by muse, mutect2
- FGR | c.1336A>G p.I446V | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.29); catalogued as rs1444183227; called by muse, mutect2
- GLIPR1L2 | c.379G>C p.E127Q | Missense Mutation (SNP) | VAF 23/743 reads (3%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.8); catalogued as COSV57554182; called by muse, mutect2
- HECW1 | c.4664G>A p.R1555Q | Missense Mutation (SNP) | VAF 20/400 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.665); catalogued as rs1341519354; called by muse, mutect2
- HRNR | c.2455C>A p.Q819K | Missense Mutation (SNP) | VAF 25/222 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV64261749; called by muse, mutect2, varscan2
- HYDIN | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 14/147 reads (10%) | catalogued as COSV55489951; called by muse, mutect2
- KCNH7 | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 23/280 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.725); catalogued as rs758119259, COSV59801779, COSV59804711; called by muse, mutect2
- KCNU1 | c.2064G>A p.M688I | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as rs545781072, COSV67754541; called by muse, mutect2
- MAGI3 | c.4076A>G p.K1359R | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as rs764166194; called by muse, mutect2, varscan2
- MYT1L | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 9/199 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.871); catalogued as rs1219261934, COSV67711546; called by muse, mutect2
- NCAN | c.2482C>T p.P828S | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as rs761502466, COSV53050465; called by muse, mutect2
- NEB | c.4888G>T p.D1630Y | Missense Mutation (SNP) | VAF 65/643 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50918988; called by muse, mutect2, varscan2
- OR8I2 | c.694G>A p.G232S | Missense Mutation (SNP) | VAF 6/113 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV56171164; called by muse, mutect2
- PI15 | c.393-1G>T p.X131_splice | Splice Site (SNP) | VAF 12/146 reads (8%) | catalogued as COSV52639798; called by muse, mutect2
- POLD1 | c.2023G>T p.A675S | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as rs753870000; called by muse, mutect2
- PPP1CB | c.296C>G p.S99C | Missense Mutation (SNP) | VAF 9/291 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56092007, COSV99941637; called by muse, mutect2
- REN | c.880G>A p.G294S | Missense Mutation (SNP) | VAF 34/245 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65817474; called by muse, mutect2, varscan2
- RNASE1 | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 25/186 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs770257111, COSV100564523, COSV61753879; called by muse, mutect2, varscan2
- RPGRIP1 | c.1967A>G p.Y656C | Missense Mutation (SNP) | VAF 46/413 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748493769; called by muse, mutect2, varscan2
- SALL3 | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs372096716; called by muse, mutect2
- SCYL2 | c.424C>G p.P142A | Missense Mutation (SNP) | VAF 8/248 reads (3%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as rs1309487512; called by muse, mutect2
- SLC7A9 | c.1166C>T p.T389M | Missense Mutation (SNP) | VAF 46/331 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs756323038, CM148319, COSV50082944; called by muse, mutect2, varscan2
- SLIT1 | c.173A>G p.N58S | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.077); catalogued as rs1255648850; called by muse, mutect2, varscan2
- SPIRE1 | c.211G>T p.A71S | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0.023); catalogued as rs1474131871; called by muse, mutect2
- STAB1 | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.435); catalogued as rs759109499; called by muse, mutect2, varscan2
- THSD7B | c.1690C>A p.R564S | Missense Mutation (SNP) | VAF 19/238 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.579); catalogued as COSV55692365, COSV55716754; called by muse, mutect2
- UTP3 | c.1201G>A p.A401T | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as rs200408107; called by muse, mutect2, varscan2
- ZNF35 | c.1040C>G p.S347* | Nonsense Mutation (SNP) | VAF 10/66 reads (15%) | catalogued as rs1248446928; called by muse, mutect2, varscan2
- ABCA10 | c.1314C>A p.N438K | Missense Mutation (SNP) | VAF 17/344 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2
- ABCA13 | c.2782G>T p.D928Y | Missense Mutation (SNP) | VAF 52/1011 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by muse, mutect2
- ABCC1 | c.3919G>T p.D1307Y | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- ADAD1 | c.743T>C p.V248A | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ADCY2 | c.1759G>C p.V587L | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRV1 | c.11758G>T p.G3920C | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.41); called by mutect2, varscan2
- ANKRD12 | c.5588A>G p.Y1863C | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.997); called by muse, mutect2
- ANKRD30B | c.3610C>T p.H1204Y | Missense Mutation (SNP) | VAF 16/217 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.06); called by muse, mutect2
- ANKRD50 | c.4189T>C p.Y1397H | Missense Mutation (SNP) | VAF 25/246 reads (10%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ARSH | c.608T>C p.L203P | Missense Mutation (SNP) | VAF 74/566 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- ATP7B | c.4087T>G p.S1363A | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BRD1 | c.2636C>T p.A879V (on ENST00000216267 / NM_001349940.1; = p.A1010V on NM_001304808.3) | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CD101 | c.1378G>T p.V460L | Missense Mutation (SNP) | VAF 30/336 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); called by muse, mutect2
- CD72 | c.516G>T p.Q172H | Missense Mutation (SNP) | VAF 24/394 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); called by muse, mutect2
- CHRM3 | c.240G>T p.L80F | Missense Mutation (SNP) | VAF 16/203 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.728); called by muse, mutect2
- CHRNA1 | c.164T>A p.L55Q | Missense Mutation (SNP) | VAF 24/563 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- COL17A1 | c.1385G>A p.C462Y | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CSRNP3 | c.351C>A p.H117Q | Missense Mutation (SNP) | VAF 30/338 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- CYYR1 | c.280A>C p.T94P | Missense Mutation (SNP) | VAF 25/271 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2
- DNAAF5 | c.1309C>G p.L437V | Missense Mutation (SNP) | VAF 11/247 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.397); called by muse, mutect2
- DRD5 | c.278T>A p.L93Q | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAM200B | c.473C>G p.A158G | Missense Mutation (SNP) | VAF 45/319 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- GABRR3 | c.847A>G p.M283V | Missense Mutation (SNP) | VAF 28/506 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.173); called by muse, mutect2
- GPR1 | c.1016_1026del p.Q339Lfs*43 | Frame Shift Del (DEL) | VAF 12/138 reads (9%) | called by mutect2, pindel
- GRAMD2B | c.118G>C p.D40H | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); called by muse, mutect2
- GRID1 | c.1063T>C p.S355P | Missense Mutation (SNP) | VAF 13/220 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- GRIK1 | c.1393T>C p.S465P | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- HHAT | c.1022G>C p.G341A | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); called by muse, mutect2
- ICE1 | c.4970C>G p.S1657C | Missense Mutation (SNP) | VAF 17/330 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2
- ITGB2 | c.2366A>T p.K789M (on ENST00000302347; = p.K765M on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/318 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.34); called by muse, mutect2
- ITK | c.382G>C p.G128R | Missense Mutation (SNP) | VAF 16/474 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- KCNA4 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 4/94 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- KRT16 | c.1383G>T p.E461D | Missense Mutation (SNP) | VAF 38/386 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); called by muse, mutect2
- KRTAP5-3 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- LFNG | c.23G>T p.R8L | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2
- LRRC61 | c.676A>G p.T226A | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2
- MET | c.3025_3028+5del p.X1009_splice | Splice Site (DEL) | VAF 90/436 reads (21%) | called by mutect2, pindel, varscan2
- NAP1L2 | c.34G>T p.E12* | Nonsense Mutation (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- NCOR2 | c.329T>A p.L110Q | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NRXN1 | c.3678G>C p.L1226F | Missense Mutation (SNP) | VAF 29/403 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR10A2 | c.663G>T p.K221N | Missense Mutation (SNP) | VAF 50/370 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- OR5B2 | c.470A>G p.H157R | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.703); called by muse, mutect2
- PCDH8 | c.2695C>A p.H899N | Missense Mutation (SNP) | VAF 28/304 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- PKHD1L1 | c.4953T>A p.F1651L | Missense Mutation (SNP) | VAF 16/321 reads (5%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2
- RALGAPA1 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- REPS2 | c.274-1G>C p.X92_splice | Splice Site (SNP) | VAF 19/197 reads (10%) | called by muse, mutect2, varscan2
- RNASE13 | c.13G>T p.V5L | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RUNX3 | c.587A>G p.D196G | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); called by muse, mutect2
- SETBP1 | c.2221G>A p.E741K | Missense Mutation (SNP) | VAF 14/369 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.247); called by muse, mutect2
- SLC35A5 | c.1220A>T p.E407V | Missense Mutation (SNP) | VAF 21/210 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SLC35A5 | c.1221A>T p.E407D | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SMYD4 | c.754G>C p.D252H | Missense Mutation (SNP) | VAF 26/244 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- SQSTM1 | c.122C>A p.P41Q | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.786); called by muse, mutect2
- SREBF1 | c.1785+1G>T p.X595_splice | Splice Site (SNP) | VAF 20/215 reads (9%) | called by muse, mutect2, varscan2
- TAAR6 | c.749C>G p.A250G | Missense Mutation (SNP) | VAF 14/219 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.078); called by muse, mutect2
- TBX4 | c.936G>C p.Q312H | Missense Mutation (SNP) | VAF 20/352 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); called by muse, mutect2
- TMA16 | c.507G>T p.K169N | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); called by muse, mutect2
- TRABD2A | c.191C>T p.T64I | Missense Mutation (SNP) | VAF 11/249 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TRERF1 | c.3080G>T p.R1027L | Missense Mutation (SNP) | VAF 14/165 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRIM77 | c.20A>T p.Q7L | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- TRPA1 | c.1762C>T p.L588F | Missense Mutation (SNP) | VAF 38/748 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.319); called by muse, mutect2
- TRPM5 | c.2413G>C p.D805H | Missense Mutation (SNP) | VAF 23/248 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TRPS1 | c.2711C>T p.T904I (on ENST00000220888 / NM_001330599.2; = p.T917I on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/1078 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRUB1 | c.349G>T p.G117* | Nonsense Mutation (SNP) | VAF 17/268 reads (6%) | called by muse, mutect2
- TYMP | c.417+5G>C | Splice Region (SNP) | VAF 25/326 reads (8%) | called by muse, mutect2
- UHRF1BP1L | c.47T>G p.F16C | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UTS2B | c.219C>A p.N73K | Missense Mutation (SNP) | VAF 18/362 reads (5%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2
- WDR59 | c.211G>C p.D71H | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.275); called by muse, mutect2
- WFIKKN2 | c.1174C>A p.Q392K | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.135); called by muse, mutect2
- ADAMTS2 | c.1104G>A p.R368= | Silent (SNP) | VAF 28/235 reads (12%) | called by muse, mutect2, varscan2
- ADGRF1 | c.1020C>A p.T340= | Silent (SNP) | VAF 19/262 reads (7%) | called by muse, mutect2
- C4orf54 | c.2241C>T p.V747= | Silent (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2
- CBX1 | c.405G>C p.L135= | Silent (SNP) | VAF 23/213 reads (11%) | catalogued as COSV99848148; called by muse, mutect2, varscan2
- EPHA1 | c.2310G>T p.L770= | Silent (SNP) | VAF 46/388 reads (12%) | called by muse, mutect2, varscan2
- ERBB4 | c.3147A>G p.G1049= | Silent (SNP) | VAF 58/494 reads (12%) | called by muse, mutect2, varscan2
- EVPL | c.1209C>T p.A403= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV56914566; called by muse, mutect2, varscan2
- GIPR | c.1095C>T p.A365= | Silent (SNP) | VAF 11/291 reads (4%) | catalogued as rs1316453820; called by muse, mutect2
- GLB1L | c.30T>A p.R10= | Silent (SNP) | VAF 16/244 reads (7%) | called by muse, mutect2
- GPR37 | c.552G>A p.R184= | Silent (SNP) | VAF 12/210 reads (6%) | called by muse, mutect2
- GPSM3 | c.303C>A p.L101= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV66682610; called by mutect2, varscan2
- HEATR4 | c.297C>A p.T99= | Silent (SNP) | VAF 15/197 reads (8%) | called by muse, mutect2
- KIF2B | c.1515C>T p.D505= | Silent (SNP) | VAF 39/287 reads (14%) | catalogued as COSV99274420; called by muse, mutect2, varscan2
- LENG1 | c.267G>A p.V89= | Silent (SNP) | VAF 7/122 reads (6%) | called by muse, mutect2
- MMP16 | c.1686G>A p.V562= | Silent (SNP) | VAF 66/519 reads (13%) | catalogued as rs757308005, COSV99686791; called by muse, mutect2, varscan2
- MYO19 | c.921C>G p.G307= | Silent (SNP) | VAF 26/210 reads (12%) | called by muse, mutect2, varscan2
- PLEKHH2 | c.1185C>T p.L395= | Silent (SNP) | VAF 22/474 reads (5%) | catalogued as rs1206158854, COSV56753740; called by muse, mutect2
- PRDM1 | c.399A>G p.K133= | Silent (SNP) | VAF 31/245 reads (13%) | catalogued as rs1353557226; called by muse, mutect2, varscan2
- PROM2 | c.612C>T p.V204= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as rs767060031; called by muse, mutect2, varscan2
- PROSER3 | c.27C>T p.S9= | Silent (SNP) | VAF 23/97 reads (24%) | called by muse, mutect2, varscan2
- PRPS1L1 | c.375C>T p.I125= | Silent (SNP) | VAF 16/224 reads (7%) | catalogued as rs980854242, COSV72649926; called by muse, mutect2
- RGS8 | c.36G>A p.G12= (on ENST00000367556 / NM_001369564.2; = p.G30= on NM_033345.3) | Silent (SNP) | VAF 8/223 reads (4%) | called by muse, mutect2
- RYR2 | c.6357G>C p.L2119= | Silent (SNP) | VAF 12/339 reads (4%) | called by muse, mutect2
- SLCO1C1 | c.636G>A p.L212= | Silent (SNP) | VAF 46/275 reads (17%) | catalogued as rs1220377777; called by muse, mutect2, varscan2
- TCTN2 | c.1734G>A p.G578= | Silent (SNP) | VAF 28/408 reads (7%) | called by muse, mutect2
- TTLL5 | c.2451C>T p.F817= | Silent (SNP) | VAF 8/218 reads (4%) | catalogued as COSV100091962; called by muse, mutect2
- AC026784.1 | chr5:23976005 C>T | 5'Flank (SNP) | VAF 8/53 reads (15%) | catalogued as rs1004180986; called by muse, mutect2
- ADAM10 | c.484+2877G>T | Intron (SNP) | VAF 12/141 reads (9%) | called by muse, mutect2
- CDC20B | c.580+2753T>A | Intron (SNP) | VAF 14/208 reads (7%) | called by muse, mutect2
- FAM153CP | chr5:178055699 C>T | 3'Flank (SNP) | VAF 43/360 reads (12%) | catalogued as rs1043422120; called by muse, mutect2, varscan2
- FAM228B | c.*62del | 3'UTR (DEL) | VAF 9/77 reads (12%) | called by mutect2, pindel, varscan2
- FCRL1 | c.1186+79C>A | Intron (SNP) | VAF 25/469 reads (5%) | catalogued as COSV63827521; called by muse, mutect2
- GCNT2 | c.925+27241G>T | Intron (SNP) | VAF 3/24 reads (13%) | catalogued as rs1311483205; called by muse, mutect2
- KCTD7 | c.-32del | 5'UTR (DEL) | VAF 20/172 reads (12%) | called by mutect2, varscan2
- MRPL13 | c.*27G>T | 3'UTR (SNP) | VAF 24/322 reads (7%) | called by muse, mutect2
- PDE6B | c.927+124C>A | Intron (SNP) | VAF 6/53 reads (11%) | called by muse, mutect2, varscan2
- PTPN6 | c.131+23C>T | Intron (SNP) | VAF 18/252 reads (7%) | catalogued as rs782336389; called by muse, mutect2
- RBM10 | c.-165G>C | 5'UTR (SNP) | VAF 14/174 reads (8%) | called by muse, mutect2
- STARD7-AS1 | n.1544C>T | RNA (SNP) | VAF 14/140 reads (10%) | called by muse, mutect2, varscan2
